Somatic mutation profile of tumor specimen 1105269 (aliquot 7316UP-393-1105269) from CPTAC case C266664, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen 1105269: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb2b6881-ef24-4a81-aab6-47255f1d106f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105287 (Blood Derived Normal), aliquot 7316UP-393-1105287; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8a090d0-9661-48d8-96e3-5092961b4def

The open-access MAF lists 1,252 somatic variants for this specimen: 879 protein-altering or splice-affecting, 247 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 737, Silent 247, Nonsense Mutation 58, Intron 53, Frame Shift Del 28, 5'UTR 25, Splice Site 22, 3'UTR 21, RNA 18, Frame Shift Ins 14, Splice Region 13, 5'Flank 8.

Variants (750 of 1,252; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3810T>A p.C1270* | Nonsense Mutation (SNP) | VAF 150/157 reads (96%) | catalogued as rs863225347, CM000125, CX995213, COSV57342456, COSV57383570; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 577/942 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs797045203, CM139760, COSV55671915, COSV55675820, COSV55678737; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HBA2 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 35/750 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs33933481, CM810008, COSV52406347; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 686/721 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.3857G>C p.S1286T | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100383745; called by muse, mutect2, varscan2
- ACHE | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 333/551 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814894; called by muse, mutect2, varscan2
- ACOT11 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 118/579 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59350863; called by muse, mutect2, varscan2
- ADCY8 | c.1639G>T p.G547W | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53915654; called by muse, mutect2
- ADGRB3 | c.3430G>T p.V1144F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV99486457; called by muse, mutect2
- AGBL3 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51954764; called by muse, mutect2, varscan2
- AGTR2 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64157138; called by muse, mutect2, varscan2
- ALOXE3 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 636/661 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs372027737; called by muse, mutect2, varscan2
- AMBN | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 103/151 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs372201499; called by muse, mutect2, varscan2
- ANGPT1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52449117; called by muse, mutect2, varscan2
- APAF1 | c.2834G>T p.R945L (on ENST00000551964 / NM_181861.2; = p.R891L on NM_001160.3) | Missense Mutation (SNP) | VAF 148/236 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs146420669; called by muse, mutect2, varscan2
- AR | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 127/133 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1305696138; called by muse, mutect2, varscan2
- ARMC5 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 595/624 reads (95%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1182126474, COSV99192819; called by muse, mutect2, varscan2
- ASCC3 | c.6275G>T p.G2092V | Missense Mutation (SNP) | VAF 204/216 reads (94%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100976164; called by muse, mutect2, varscan2
- ASTN2 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100528087; called by muse, mutect2, varscan2
- ATP2A2 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 198/298 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875265, COSV57876016; called by muse, mutect2, varscan2
- ATXN1 | c.837C>G p.H279Q | Missense Mutation (SNP) | VAF 122/201 reads (61%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as COSV55207534; called by muse, mutect2, varscan2
- AXDND1 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 59/141 reads (42%) | catalogued as COSV62641362; called by muse, mutect2, varscan2
- B4GALT1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 126/138 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1177565118, COSV65709015; called by muse, mutect2, varscan2
- BCL6 | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 204/294 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51656145; called by muse, mutect2, varscan2
- BIN1 | c.1397G>C p.G466A (on ENST00000316724 / NM_001320642.1; = p.G327A on NM_004305.4) | Missense Mutation (SNP) | VAF 412/824 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs762512900; called by muse, mutect2, varscan2
- BRINP1 | c.2005C>A p.L669M | Missense Mutation (SNP) | VAF 169/281 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV56302494, COSV56307679; called by muse, mutect2, varscan2
- BTBD11 | c.3138C>G p.C1046W (on ENST00000280758 / NM_001018072.2; = p.C583W on NM_001017523.2) | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55028759; called by muse, mutect2, varscan2
- BTBD11 | c.3139G>A p.E1047K (on ENST00000280758 / NM_001018072.2; = p.E584K on NM_001017523.2) | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs34000924; called by muse, mutect2, varscan2
- C1orf87 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 270/561 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs750065570; called by muse, mutect2, varscan2
- CACNA2D1 | c.1590G>C p.K530N | Missense Mutation (SNP) | VAF 140/225 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV62385745; called by muse, mutect2, varscan2
- CACNA2D1 | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV62371428; called by muse, mutect2, varscan2
- CBLL1 | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV56031141; called by muse, mutect2, varscan2
- CCDC168 | c.14264C>A p.P4755Q | Missense Mutation (SNP) | VAF 146/163 reads (90%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV59423319; called by muse, mutect2, varscan2
- CCDC171 | c.2443A>C p.K815Q | Missense Mutation (SNP) | VAF 212/224 reads (95%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs756614235; called by muse, mutect2, varscan2
- CCDC40 | c.2309C>A p.A770E | Missense Mutation (SNP) | VAF 96/1320 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100884351; called by muse, mutect2
- CCRL2 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs376131944, COSV62193378; called by muse, mutect2, varscan2
- CD6 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs371896389; called by muse, mutect2, varscan2
- CDH23 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 171/341 reads (50%) | catalogued as CM118623; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1711C>A p.L571M | Missense Mutation (SNP) | VAF 266/428 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100575746; called by muse, mutect2, varscan2
- CEBPB | c.263del p.P88Rfs*53 | Frame Shift Del (DEL) | VAF 219/418 reads (52%) | catalogued as rs1213951106; called by mutect2, pindel, varscan2
- CFAP61 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 66/176 reads (38%) | catalogued as COSV55621866; called by muse, mutect2, varscan2
- CFAP69 | c.1533G>T p.M511I | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60188600; called by muse, mutect2, varscan2
- CFAP69 | c.2822C>T p.T941M | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs376414901; called by muse, mutect2, varscan2
- CHCHD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 123/245 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs756273254; called by muse, mutect2, varscan2
- CHGB | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 110/248 reads (44%) | catalogued as rs560272361, COSV66760876; called by muse, mutect2, varscan2
- CHRM3 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 123/141 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs202097685, COSV55093350, COSV99697259; called by muse, varscan2
- CNTN6 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 75/121 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs368850185, COSV63162057; called by muse, mutect2, varscan2
- CNTNAP5 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70502012; called by muse, mutect2, varscan2
- COL11A1 | c.4159G>T p.G1387C | Missense Mutation (SNP) | VAF 219/388 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100615438; called by muse, mutect2, varscan2
- COL19A1 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 158/170 reads (93%) | SIFT tolerated (0.5); PolyPhen benign (0.247); catalogued as COSV100505503, COSV59572208; called by muse, mutect2, varscan2
- COL22A1 | c.3856G>T p.A1286S | Missense Mutation (SNP) | VAF 182/428 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV57335844; called by muse, mutect2, varscan2
- COL6A5 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339825242; called by muse, mutect2, varscan2
- COL9A3 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59654062; called by muse, mutect2, varscan2
- CPED1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100119808; called by muse, mutect2, varscan2
- CSMD1 | c.3002C>A p.T1001N (on ENST00000520002; = p.T1000N on NM_033225.6) | Missense Mutation (SNP) | VAF 296/627 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59294813; called by muse, varscan2
- CTU1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 129/417 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1396291989; called by muse, mutect2, varscan2
- CUX2 | c.3901G>C p.E1301Q | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as COSV55627940, COSV55628772; called by muse, mutect2, varscan2
- DIRAS3 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.172); catalogued as rs761694570; called by muse, mutect2, varscan2
- DLGAP1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs752354203; called by muse, mutect2, varscan2
- DMBT1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs758442204; called by muse, mutect2, varscan2
- DMXL1 | c.8329C>T p.Q2777* | Nonsense Mutation (SNP) | VAF 130/143 reads (91%) | catalogued as COSV100224014, COSV100225269; called by muse, mutect2, varscan2
- DNAH7 | c.5764-1G>T p.X1922_splice | Splice Site (SNP) | VAF 108/215 reads (50%) | catalogued as COSV56751522; called by muse, mutect2, varscan2
- DNAJB4 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1352636432; called by muse, mutect2, varscan2
- DYSF | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 235/636 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM053212, COSV50483645; called by muse, mutect2, varscan2
- EDIL3 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99676277; called by muse, mutect2, varscan2
- EFR3B | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 103/268 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV104391905; called by muse, mutect2, varscan2
- ELAPOR2 | c.850del p.V284Wfs*41 (on ENST00000450689 / NM_001142749.3; = p.V117Wfs*41 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/135 reads (30%) | catalogued as COSV99789566; called by mutect2, pindel, varscan2
- EML3 | c.1978G>T p.G660W | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99604182; called by muse, mutect2, varscan2
- EPHB1 | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV104432561; called by muse, mutect2, varscan2
- EPO | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773297902; called by muse, mutect2, varscan2
- ERICH3 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 403/521 reads (77%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV58605596; called by muse, mutect2, varscan2
- ETS2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 297/630 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs1411415689; called by muse, mutect2, varscan2
- EVX1 | c.903C>A p.S301R | Missense Mutation (SNP) | VAF 353/550 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99764062; called by muse, mutect2, varscan2
- EZHIP | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 289/298 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100539677; called by muse, mutect2, varscan2
- F5 | c.4375G>C p.D1459H | Missense Mutation (SNP) | VAF 212/528 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63123687, COSV63129999; called by muse, mutect2, varscan2
- F9 | c.1070del p.G357Efs*11 | Frame Shift Del (DEL) | VAF 101/143 reads (71%) | catalogued as rs1198183173, CM094094, CM940636, CM990576; called by mutect2, pindel, varscan2
- FABP1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99860851; called by muse, mutect2, varscan2
- FAM135B | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777900338, COSV52730648; called by muse, mutect2, varscan2
- FAM151B | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1304437732; called by muse, mutect2
- FAM47A | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.077); catalogued as rs764600575, COSV100649805; called by muse, mutect2, varscan2
- FAM47C | c.2288G>T p.R763L | Missense Mutation (SNP) | VAF 370/406 reads (91%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100792410; called by muse, mutect2, varscan2
- FBN3 | c.6796_6810del p.G2266_N2270del | In Frame Del (DEL) | VAF 45/68 reads (66%) | catalogued as rs767570831; called by mutect2, varscan2
- FBXO40 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 243/312 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57524332; called by muse, mutect2, varscan2
- FIZ1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 122/410 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs1471901175, COSV55607217, COSV99684747; called by muse, mutect2, varscan2
- FMN2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV100146758; called by muse, mutect2, varscan2
- FRMD6 | c.532G>C p.E178Q (on ENST00000344768 / NM_001267046.2; = p.E170Q on NM_152330.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs781384641, COSV100656397; called by muse, mutect2
- FYB1 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 246/441 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60952116; called by muse, mutect2, varscan2
- GAD2 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1243932259, COSV99393155; called by muse, mutect2, varscan2
- GBA3 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 204/315 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV72438551; called by muse, mutect2, varscan2
- GDPD4 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1034560793, COSV60016915, COSV60018216; called by muse, mutect2, varscan2
- GHR | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 124/426 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100050195; called by muse, mutect2, varscan2
- GRM8 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 167/283 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV58808223; called by muse, mutect2, varscan2
- GTPBP10 | c.320-2A>G p.X107_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | catalogued as COSV55987949; called by muse, mutect2
- GUCY2D | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 357/373 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs750895890; called by muse, mutect2, varscan2
- GYS2 | c.1425G>A p.V475= | Splice Region (SNP) | VAF 52/224 reads (23%) | catalogued as COSV53925751; called by muse, mutect2, varscan2
- HBA2 | c.380A>T p.D127V | Missense Mutation (SNP) | VAF 36/743 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs33957766, CM034426; called by muse, mutect2
- HECTD4 | c.6448G>T p.A2150S | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.998); catalogued as COSV101108025; called by muse, mutect2
- HEPHL1 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 150/247 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59890126; called by muse, varscan2
- HERC1 | c.14123G>C p.W4708S | Missense Mutation (SNP) | VAF 116/122 reads (95%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.998); catalogued as COSV71250596; called by muse, mutect2, varscan2
- HS6ST3 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 109/118 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs141432230; called by muse, mutect2, varscan2
- HSPG2 | c.10855A>C p.S3619R | Missense Mutation (SNP) | VAF 329/673 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV65933030; called by muse, mutect2, varscan2
- IGLV11-55 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101135393; called by muse, mutect2, varscan2
- IGSF8 | c.1555G>T p.V519L | Missense Mutation (SNP) | VAF 166/368 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV58758476; called by muse, mutect2, varscan2
- IL21R | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 348/376 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs371591899; called by muse, mutect2, varscan2
- IL5RA | c.1061T>A p.I354N | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs1204865704; called by muse, mutect2, varscan2
- INPP5D | c.2615G>T p.R872L (on ENST00000445964 / NM_001017915.3; = p.R871L on NM_005541.5) | Missense Mutation (SNP) | VAF 193/441 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV64036256; called by muse, mutect2, varscan2
- IPO5 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as rs760493969; called by muse, mutect2, varscan2
- IPO7 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs772562320, COSV65686634; called by muse, mutect2, varscan2
- ITGA8 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1381764651; called by muse, mutect2, varscan2
- KALRN | c.4553C>T p.T1518M | Missense Mutation (SNP) | VAF 179/228 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs780998165, COSV53758713; called by muse, mutect2, varscan2
- KCNA6 | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV54976035; called by muse, mutect2, varscan2
- KCNE4 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 214/541 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427983334; called by muse, mutect2, varscan2
- KCNG4 | c.1264G>C p.G422R | Missense Mutation (SNP) | VAF 128/135 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377056; called by muse, mutect2, varscan2
- KCNT1 | c.3010G>T p.G1004C (on ENST00000488444; = p.G1023C on NM_020822.3) | Missense Mutation (SNP) | VAF 139/226 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104375601; called by muse, mutect2, varscan2
- KHDC1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 121/135 reads (90%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs1562263204; called by muse, mutect2, varscan2
- KIAA1109 | c.9407C>A p.P3136H | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52673100; called by muse, mutect2, varscan2
- KLF7 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 111/215 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.327); catalogued as COSV100519073; called by muse, mutect2, varscan2
- KLHL29 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs1173388681; called by muse, mutect2, varscan2
- KNDC1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1359217204; called by muse, mutect2, varscan2
- KRT31 | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 156/304 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV104381206; called by muse, mutect2, varscan2
- KRTAP19-1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 226/485 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.21); catalogued as COSV66860928, COSV66861078; called by muse, mutect2, varscan2
- KRTAP22-2 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 106/206 reads (51%) | PolyPhen benign (0); catalogued as rs1388057362; called by muse, mutect2, varscan2
- KRTAP5-11 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 382/560 reads (68%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100651805; called by muse, mutect2, varscan2
- KRTAP6-3 | c.45C>A p.N15K | Missense Mutation (SNP) | VAF 124/256 reads (48%) | PolyPhen probably damaging (0.909); catalogued as COSV66963409; called by muse, mutect2, varscan2
- KYAT3 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 79/115 reads (69%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs769215372; called by muse, mutect2, varscan2
- LGI2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV66124311; called by muse, mutect2
- LGI2 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV66123674; called by muse, mutect2, varscan2
- LINGO4 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 134/276 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); catalogued as COSV59093192; called by muse, mutect2, varscan2
- LMO4 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 235/351 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100983997; called by muse, mutect2, varscan2
- LPP | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 461/601 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs762236261; called by muse, mutect2, varscan2
- LRRC7 | c.2791C>A p.P931T (on ENST00000651989 / NM_001370785.2; = p.P898T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 320/415 reads (77%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); catalogued as COSV99224356; called by muse, mutect2, varscan2
- MAP2 | c.3886C>G p.Q1296E | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52296184; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99151156; called by muse, mutect2, varscan2
- MARK1 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 261/284 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs1165050058; called by muse, mutect2, varscan2
- MBD3L3 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 105/358 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs904709946; called by mutect2, varscan2
- MBTPS1 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 150/169 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58570544; called by muse, mutect2, varscan2
- MEGF8 | c.8170G>A p.A2724T (on ENST00000251268 / NM_001271938.2; = p.A2657T on NM_001410.3) | Missense Mutation (SNP) | VAF 150/309 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs530619835, COSV52104254; called by muse, mutect2, varscan2
- MGA | c.4031G>T p.W1344L | Missense Mutation (SNP) | VAF 70/75 reads (93%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV54953317; called by muse, mutect2, varscan2
- MMP3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as COSV100243024; called by muse, mutect2, varscan2
- MPIG6B | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 174/183 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1400142656, COSV65390338; called by muse, mutect2, varscan2
- MROH2B | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 151/239 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV68189770; called by muse, mutect2, varscan2
- MSH4 | c.2161A>G p.T721A | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs762051663; called by muse, mutect2, varscan2
- MTTP | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 256/402 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748681503, COSV55507564, COSV99644913; called by muse, mutect2, varscan2
- MTUS2 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 96/99 reads (97%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV101462271; called by muse, mutect2, varscan2
- MUC16 | c.41503G>T p.V13835F | Missense Mutation (SNP) | VAF 128/145 reads (88%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as rs781428326; called by muse, mutect2, varscan2
- MUC17 | c.3914C>G p.T1305S | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs763406863; called by muse, mutect2, varscan2
- MUC17 | c.11123G>A p.S3708N | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV60294101; called by muse, mutect2, varscan2
- MUC22 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 140/147 reads (95%) | SIFT deleterious, low confidence (0.02); catalogued as rs1469259269; called by muse, mutect2, varscan2
- MUC5B | c.10816G>A p.G3606R | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs372672550; called by muse, mutect2, varscan2
- MYBL2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 126/213 reads (59%) | catalogued as COSV53829661; called by muse, mutect2, varscan2
- MYH1 | c.5422G>T p.A1808S | Missense Mutation (SNP) | VAF 221/236 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV56857151; called by muse, mutect2, varscan2
- NALCN | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 73/78 reads (94%) | catalogued as COSV51917306, COSV51932503; called by muse, mutect2, varscan2
- NAV3 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99888513; called by muse, mutect2, varscan2
- NBEAL1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 48/110 reads (44%) | catalogued as rs773758454; called by muse, mutect2, varscan2
- NCKAP5L | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.296); catalogued as rs774089943; called by muse, mutect2, varscan2
- NEXMIF | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 150/160 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50023282; called by muse, mutect2, varscan2
- NLGN1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 294/384 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64349101; called by muse, mutect2, varscan2
- NLGN4X | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 310/326 reads (95%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.333); catalogued as COSV52012012; called by muse, mutect2, varscan2
- NOTCH2 | c.2440A>G p.I814V | Missense Mutation (SNP) | VAF 234/371 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782757612; called by muse, mutect2, varscan2
- NOTCH4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs1304701623, COSV66681126; called by muse, mutect2
- NPBWR2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 152/256 reads (59%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370307704; called by muse, mutect2, varscan2
- NPY2R | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV61527622; called by muse, mutect2, varscan2
- NRROS | c.1641del p.L548* | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as COSV100145401; called by mutect2, varscan2
- OR10G3 | c.831del p.T278Rfs*19 | Frame Shift Del (DEL) | VAF 70/267 reads (26%) | catalogued as COSV100336118; called by mutect2, pindel, varscan2
- OR4C16 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58942770; called by muse, mutect2, varscan2
- OR4K1 | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99579397; called by muse, mutect2, varscan2
- OR8K3 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57131466; called by muse, mutect2, varscan2
- OSBPL5 | c.2467C>T p.L823F | Missense Mutation (SNP) | VAF 129/207 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.24); catalogued as rs1227879264; called by muse, mutect2, varscan2
- PCDHGB1 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 281/299 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs930490756; called by muse, mutect2, varscan2
- PCNT | c.6889G>A p.A2297T | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs959271732; called by muse, mutect2, varscan2
- PDE1B | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 92/155 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV99226348; called by muse, mutect2, varscan2
- PDP1 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 336/749 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892212; called by muse, mutect2, varscan2
- PERM1 | c.1359C>A p.D453E | Missense Mutation (SNP) | VAF 259/719 reads (36%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.62); catalogued as rs776964907; called by muse, mutect2, varscan2
- PKHD1L1 | c.2494G>T p.G832* | Nonsense Mutation (SNP) | VAF 69/111 reads (62%) | catalogued as COSV65749315; called by muse, mutect2, varscan2
- PLBD2 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 89/354 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs1304164084; called by muse, mutect2, varscan2
- PNPLA6 | c.3112G>T p.E1038* (on ENST00000414982 / NM_001166111.2; = p.E990* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 245/258 reads (95%) | catalogued as COSV99075571; called by muse, mutect2, varscan2
- POLD1 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70956804; called by muse, mutect2, varscan2
- POLE4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1269666375; called by muse, mutect2, varscan2
- POTEF | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 171/1254 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV62544059; called by muse, mutect2, varscan2
- PPFIBP1 | c.2287G>T p.V763F (on ENST00000318304 / NM_177444.3; = p.V757F on NM_003622.4) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363429727, COSV57292903; called by muse, mutect2, varscan2
- PRAMEF4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 708/751 reads (94%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV52437958; called by muse, mutect2, varscan2
- PRDM8 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs752993100; called by muse, varscan2
- PRDM9 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 299/947 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs184753683; called by muse, mutect2, varscan2
- PRSS58 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 106/175 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV73488797; called by muse, mutect2, varscan2
- PTCHD3 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.029); catalogued as COSV71256775; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 107/347 reads (31%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- RASGRF2 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 286/583 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54130199; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 197/341 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV101208255; called by muse, mutect2, varscan2
- ROBO2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 216/237 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV59922831; called by muse, mutect2, varscan2
- RP1L1 | c.2965G>T p.G989C | Missense Mutation (SNP) | VAF 415/874 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101223271; called by muse, mutect2, varscan2
- RRP12 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 134/295 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs774617555; called by muse, mutect2, varscan2
- RUFY2 | c.231del p.L78Cfs*12 | Frame Shift Del (DEL) | VAF 67/133 reads (50%) | catalogued as rs751531309; called by mutect2, varscan2
- S100A5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62876468; called by muse, mutect2, varscan2
- S100A7L2 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV64194761; called by muse, mutect2, varscan2
- SALL4 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 231/806 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53854576; called by muse, mutect2, varscan2
- SATL1 | c.350C>A p.S117* (on ENST00000395409; = p.S304* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 283/292 reads (97%) | catalogued as COSV60577984; called by muse, mutect2, varscan2
- SECTM1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 346/1158 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1439174252; called by muse, mutect2, varscan2
- SETD1B | c.5059G>T p.G1687C | Missense Mutation (SNP) | VAF 149/269 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs553963413; called by muse, mutect2, varscan2
- SH3RF3 | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100514096; called by muse, mutect2, varscan2
- SIGLEC10 | c.1083C>A p.N361K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.407); catalogued as rs1314831849; called by muse, mutect2, varscan2
- SIGLEC7 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs771941732; called by muse, mutect2, varscan2
- SLC22A25 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1272844107; called by muse, mutect2, varscan2
- SLC30A10 | c.1382G>C p.S461T | Missense Mutation (SNP) | VAF 150/157 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV63076390; called by muse, mutect2, varscan2
- SLC35G5 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 232/514 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.081); catalogued as rs764168543; called by muse, varscan2
- SLITRK2 | c.313del p.A105Hfs*5 | Frame Shift Del (DEL) | VAF 162/234 reads (69%) | catalogued as COSV59424912; called by mutect2, pindel, varscan2
- SLITRK4 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100567516; called by muse, mutect2, varscan2
- SNTG1 | c.707T>A p.V236E | Missense Mutation (SNP) | VAF 158/363 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1241317655; called by muse, mutect2, varscan2
- SPAG16 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100530410; called by muse, mutect2, varscan2
- SSX3 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 280/293 reads (96%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV53643939, COSV53646757; called by muse, mutect2, varscan2
- ST3GAL4 | c.193G>T p.D65Y (on ENST00000392669 / NM_001254758.1; = p.D61Y on NM_006278.3) | Missense Mutation (SNP) | VAF 229/363 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV57109437; called by muse, mutect2, varscan2
- ST8SIA1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 128/229 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0.174); catalogued as rs565011134; called by muse, mutect2, varscan2
- STK11 | c.443T>C p.F148S | Missense Mutation (SNP) | VAF 201/221 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58829789; called by muse, mutect2, varscan2
- SUGCT | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 88/154 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1203172280; called by muse, mutect2
- SULF2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 236/396 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.774); catalogued as rs373180984; called by muse, mutect2, varscan2
- SVEP1 | c.3212C>A p.S1071* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as COSV57029663; called by muse, mutect2, varscan2
- SYT12 | c.765G>C p.E255D | Missense Mutation (SNP) | VAF 194/658 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs778042037; called by muse, mutect2, varscan2
- TACO1 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 188/383 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51976360; called by muse, mutect2, varscan2
- TBC1D1 | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 307/529 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs151143743; called by muse, mutect2, varscan2
- TIAM1 | c.4346G>T p.R1449L | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV54554620; called by muse, mutect2, varscan2
- TIFAB | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 348/374 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV72345691; called by muse, mutect2, varscan2
- TLR5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 93/100 reads (93%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60558213, COSV60560154; called by muse, mutect2, varscan2
- TMEM161A | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 170/184 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50776683; called by muse, mutect2, varscan2
- TMEM178B | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 192/318 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV73803549; called by muse, mutect2, varscan2
- TMEM179 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 127/132 reads (96%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs1433425536; called by muse, mutect2, varscan2
- TMPRSS11A | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 42/77 reads (55%) | catalogued as COSV100602790; called by muse, mutect2, varscan2
- TRBV20-1 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 151/259 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760783607; called by muse, mutect2, varscan2
- TRIM65 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 353/1157 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1256281792, COSV99485496; called by muse, mutect2, varscan2
- TRIM9 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 280/305 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs762640179, COSV53612436; called by muse, mutect2, varscan2
- TRPV5 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 233/403 reads (58%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV99520590; called by muse, mutect2, varscan2
- TTC29 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100283640; called by muse, mutect2, varscan2
- TTLL5 | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759872181, COSV100089536; called by muse, mutect2, varscan2
- TWIST1 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CD013661, CD982422, CM060093; called by muse, mutect2, varscan2
- UNC45A | c.2350A>G p.M784V | Missense Mutation (SNP) | VAF 225/245 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV67793621; called by muse, mutect2, varscan2
- UNC5D | c.2752C>A p.L918M | Missense Mutation (SNP) | VAF 308/708 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54782165; called by muse, mutect2, varscan2
- USP4 | c.1692G>T p.V564= | Splice Region (SNP) | VAF 33/128 reads (26%) | catalogued as COSV55537742; called by muse, mutect2, varscan2
- VGLL3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 114/122 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs962129357; called by muse, mutect2, varscan2
- VIRMA | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 126/304 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV99889412; called by muse, mutect2, varscan2
- WBP1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 152/315 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776821607; called by muse, mutect2, varscan2
- WDR90 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 234/249 reads (94%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV53471855; called by muse, varscan2
- WNT10A | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 152/353 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51463831; called by muse, mutect2, varscan2
- XDH | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV65150813; called by muse, mutect2, varscan2
- XIRP2 | c.8311G>C p.E2771Q (on ENST00000628543; = p.E2946Q on NM_152381.6) | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV99737015; called by muse, mutect2, varscan2
- ZNF225 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 41/156 reads (26%) | catalogued as COSV53471936; called by muse, mutect2, varscan2
- ZNF536 | c.2168C>A p.S723* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV100835538, COSV62817472; called by muse, mutect2, varscan2
- ZNF684 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.67); catalogued as rs1323868688; called by muse, mutect2, varscan2
- ZNF761 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 188/322 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0.037); catalogued as COSV100483334; called by muse, mutect2, varscan2
- ZNF804B | c.2438A>T p.N813I | Missense Mutation (SNP) | VAF 98/148 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV60863770; called by muse, mutect2, varscan2
- ZNF830 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 111/461 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV58490749; called by muse, mutect2, varscan2
- AASDH | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ABCA13 | c.14034C>A p.D4678E | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCC8 | c.2872G>T p.A958S | Missense Mutation (SNP) | VAF 320/486 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCG1 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 300/646 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ABI3 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ACSM5 | c.833C>A p.A278E | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ACTA2 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 280/632 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAD1 | c.306C>G p.H102Q | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM9 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 149/345 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2221dup p.E741Gfs*6 | Frame Shift Ins (INS) | VAF 106/174 reads (61%) | called by pindel, varscan2
- ADCY3 | c.954C>G p.V318= | Splice Region (SNP) | VAF 92/206 reads (45%) | called by muse, mutect2, varscan2
- ADGRB1 | c.2705G>T p.G902V | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ADGRG4 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ADGRL2 | c.2555G>T p.W852L (on ENST00000370717 / NM_001366005.1; = p.W839L on NM_012302.4) | Missense Mutation (SNP) | VAF 68/414 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ADGRL4 | c.22+7G>T | Splice Region (SNP) | VAF 64/176 reads (36%) | called by muse, mutect2, varscan2
- ADH1C | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 62/100 reads (62%) | called by muse, mutect2, varscan2
- AFF3 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 128/250 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AGFG1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 185/457 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AGO4 | c.2446A>G p.R816G | Missense Mutation (SNP) | VAF 69/443 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AHCYL2 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 188/533 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AJAP1 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 309/883 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1C1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- AKR1C2 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- ALDH8A1 | c.1311G>C p.K437N | Missense Mutation (SNP) | VAF 235/248 reads (95%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- ALPL | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 344/367 reads (94%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AMBP | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 142/276 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AMOTL2 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 167/673 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMY2B | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 214/935 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ANKRD30B | c.1994C>A p.A665D | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANKRD30BL | c.678A>C p.P226= | Splice Region (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- ANKRD60 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- AP1B1 | c.2264C>G p.A755G | Missense Mutation (SNP) | VAF 102/235 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBB2 | c.1378A>C p.T460P (on ENST00000295974 / NM_001166050.2; = p.T461P on NM_004307.2) | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLP2 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- APLP2 | c.2107G>T p.V703L | Missense Mutation (SNP) | VAF 111/170 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- APOB | c.12082C>A p.P4028T | Missense Mutation (SNP) | VAF 83/488 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP11 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 86/150 reads (57%) | called by muse, mutect2, varscan2
- AQP6 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARFIP2 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 135/218 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP23 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP28 | c.2178A>C p.Q726H (on ENST00000383472 / NM_001366230.1; = p.Q567H on NM_001010000.3) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARID5B | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 180/394 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ARMC2 | c.567del p.S190Vfs*6 | Frame Shift Del (DEL) | VAF 136/191 reads (71%) | called by mutect2, pindel, varscan2
- ASB7 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 408/429 reads (95%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ASCC2 | c.2242C>A p.R748S | Missense Mutation (SNP) | VAF 71/382 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ASCC2 | c.2241C>A p.D747E | Missense Mutation (SNP) | VAF 73/393 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ATAD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A4 | c.2304G>A p.M768I | Missense Mutation (SNP) | VAF 266/353 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 263/653 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ATRX | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATRX | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- AUTS2 | c.3133A>G p.M1045V | Missense Mutation (SNP) | VAF 153/250 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- B4GALNT3 | c.2534+1G>T p.X845_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- BACE2 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BHMG1 | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BIRC6 | c.7309G>T p.D2437Y | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BOD1L1 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- BPI | c.552G>T p.W184C (on ENST00000262865; = p.W180C on NM_001725.3) | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BPTF | c.6508G>T p.G2170* | Nonsense Mutation (SNP) | VAF 73/153 reads (48%) | called by muse, mutect2, varscan2
- BRD1 | c.2646_2649dup p.H884Tfs*9 (on ENST00000216267 / NM_001349940.1; = p.H1015Tfs*9 on NM_001304808.3) | Frame Shift Ins (INS) | VAF 77/376 reads (20%) | called by mutect2, pindel, varscan2
- BRDT | c.445+8A>T | Splice Region (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- BST1 | c.487T>A p.C163S | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTG3 | c.21del p.V8Lfs*8 | Frame Shift Del (DEL) | VAF 59/161 reads (37%) | called by mutect2, pindel, varscan2
- C17orf99 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 370/660 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- C17orf99 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 372/667 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- C1QC | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C20orf203 | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 112/210 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- C4orf17 | c.628+1G>T p.X210_splice | Splice Site (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- C8A | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 232/502 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C9 | c.69C>A p.Y23* | Nonsense Mutation (SNP) | VAF 85/391 reads (22%) | called by muse, mutect2, varscan2
- CABS1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNA1H | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNG5 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CALCOCO2 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CAMK4 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.33); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CAMK4 | c.1205_1212del p.K402Rfs*7 | Frame Shift Del (DEL) | VAF 45/51 reads (88%) | called by mutect2, pindel, varscan2
- CASQ2 | c.1077G>C p.E359D | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CASTOR2 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 460/778 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CAVIN4 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CBX2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 348/1232 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CBX4 | c.558_576del p.D187Tfs*19 | Frame Shift Del (DEL) | VAF 60/246 reads (24%) | called by pindel, varscan2
- CCDC105 | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CCDC166 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CCDC169 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CCDC171 | c.2941C>G p.Q981E | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC180 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 103/115 reads (90%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CCDC61 | c.1160A>C p.Q387P | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); called by muse, varscan2
- CCDC61 | c.1161G>C p.Q387H | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.153); called by muse, varscan2
- CCDC61 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- CCDC73 | c.2059C>A p.Q687K | Missense Mutation (SNP) | VAF 108/189 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC81 | c.917_919dup p.E306_M307insK (on ENST00000445632 / NM_001156474.2; = p.E216_M217insK on NM_021827.4) | In Frame Ins (INS) | VAF 73/142 reads (51%) | called by mutect2, pindel, varscan2
- CCL18 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 169/383 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCNE2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 45/80 reads (56%) | called by muse, mutect2, varscan2
- CCT8L2 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 87/749 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD177 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CD274 | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 108/116 reads (93%) | called by muse, mutect2, varscan2
- CD320 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 367/401 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CD38 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CDC14C | c.1230C>G p.Y410* (on ENST00000428251; = p.Y303* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 91/472 reads (19%) | called by muse, varscan2
- CDH4 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CDHR2 | c.2356C>A p.Q786K | Missense Mutation (SNP) | VAF 113/117 reads (97%) | SIFT tolerated (0.86); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CDK11A | c.919A>T p.T307S (on ENST00000378633 / NM_001313896.2; = p.T304S on NM_024011.4) | Missense Mutation (SNP) | VAF 107/597 reads (18%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK13 | c.2221del p.E741Kfs*27 | Frame Shift Del (DEL) | VAF 108/255 reads (42%) | called by mutect2, pindel, varscan2
- CDON | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 201/329 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CECR2 | c.3887C>G p.P1296R (on ENST00000342247 / NM_001290047.2; = p.P1112R on NM_001290046.1) | Missense Mutation (SNP) | VAF 67/380 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CELF2 | c.1287C>A p.H429Q (on ENST00000416382 / NM_001025077.3; = p.H442Q on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPE | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- CEP350 | c.7193A>G p.E2398G | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CFAP46 | c.4598T>A p.L1533Q | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CFAP46 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP54 | c.6497G>C p.G2166A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.239); called by muse, mutect2
- CGREF1 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 226/486 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, varscan2
- CHAF1A | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 91/96 reads (95%) | SIFT tolerated (0.38); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CHAT | c.1082G>T p.W361L | Missense Mutation (SNP) | VAF 202/464 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAT | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 278/585 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD4 | c.4639G>A p.A1547T (on ENST00000357008 / NM_001363606.2; = p.A1560T on NM_001273.5) | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD4 | c.3110G>T p.G1037V (on ENST00000357008 / NM_001363606.2; = p.G1050V on NM_001273.5) | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD8 | c.2346_2362del p.P783Efs*16 (on ENST00000646647 / NM_001170629.2; = p.P504Efs*16 on NM_020920.4) | Frame Shift Del (DEL) | VAF 103/182 reads (57%) | called by mutect2, pindel, varscan2
- CHD9 | c.8374G>T p.A2792S (on ENST00000398510 / NM_001382353.1; = p.A2776S on NM_025134.7) | Missense Mutation (SNP) | VAF 129/136 reads (95%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CHRDL2 | c.1239G>T p.Q413H (on ENST00000376332 / NM_001304415.1; = p.D432Y on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CHRM1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHRM4 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 75/114 reads (66%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CMKLR1 | c.631C>A p.P211T (on ENST00000312143 / NM_001142344.2; = p.P209T on NM_004072.3) | Missense Mutation (SNP) | VAF 200/331 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.6571A>T p.T2191S | Missense Mutation (SNP) | VAF 122/258 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CMYA5 | c.8510C>T p.P2837L | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CNGB3 | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 224/479 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CNTN1 | c.1882dup p.S628Ffs*5 | Frame Shift Ins (INS) | VAF 39/235 reads (17%) | called by mutect2, pindel, varscan2
- CNTNAP3 | c.3475G>T p.A1159S | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.854); called by muse, mutect2
- CNTNAP5 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 199/448 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL12A1 | c.5442del p.K1814Nfs*22 | Frame Shift Del (DEL) | VAF 40/59 reads (68%) | called by mutect2, pindel, varscan2
- COL16A1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 549/558 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- COL2A1 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 129/238 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- COMMD10 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 140/152 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- COPS8 | c.150-1G>A p.X50_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- CPE | c.1333G>T p.V445F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, varscan2
- CPEB2 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 260/430 reads (60%) | SIFT tolerated, low confidence (0.12); called by muse, varscan2
- CREM | c.729G>T p.M243I (on ENST00000429130; = p.M19I on NM_182717.2) | Missense Mutation (SNP) | VAF 126/300 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRKL | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 243/531 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CRYBA4 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 303/711 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CRYGA | c.10-1G>T p.X4_splice | Splice Site (SNP) | VAF 117/266 reads (44%) | called by muse, mutect2, varscan2
- CSN2 | c.*36+1G>T | Splice Site (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- CSTA | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CUX1 | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CYP11B2 | c.1122G>C p.R374= | Splice Region (SNP) | VAF 155/696 reads (22%) | called by muse, mutect2
- CYP1B1 | c.145dup p.S49Ffs*175 | Frame Shift Ins (INS) | VAF 84/376 reads (22%) | called by mutect2, pindel, varscan2
- DAAM2 | c.1787dup p.R597Afs*19 | Frame Shift Ins (INS) | VAF 69/256 reads (27%) | called by mutect2, varscan2
- DBX2 | c.726del p.N243Ifs*16 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, pindel, varscan2
- DCAF17 | c.1031G>C p.W344S | Missense Mutation (SNP) | VAF 149/307 reads (49%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DCBLD1 | c.906_907del p.D303Qfs*2 | Frame Shift Del (DEL) | VAF 214/313 reads (68%) | called by mutect2, pindel, varscan2
- DDR2 | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 239/552 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DDX3X | c.1741G>T p.G581C (on ENST00000399959; = p.G582C on NM_001356.5) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DDX60L | c.3217A>T p.K1073* | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- DENND5B | c.1833T>A p.Y611* | Nonsense Mutation (SNP) | VAF 33/158 reads (21%) | called by muse, mutect2, varscan2
- DGKZ | c.3339G>T p.Q1113H (on ENST00000454345 / NM_001105540.2; = p.Q925H on NM_003646.4) | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DHX16 | c.2411A>G p.H804R | Missense Mutation (SNP) | VAF 228/242 reads (94%) | SIFT tolerated (0.18); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DLEU7 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DLG2 | c.2550C>G p.C850W | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DLGAP3 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 266/591 reads (45%) | called by muse, mutect2, varscan2
- DLGAP5 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 142/155 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- DMXL1 | c.1660A>T p.N554Y | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.312); called by muse, mutect2
- DMXL1 | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB11 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DNAJC12 | c.298-1G>A p.X100_splice | Splice Site (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- DNM3 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 317/666 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- DOCK9 | c.5519G>C p.G1840A (on ENST00000376460 / NM_001366676.2; = p.G1841A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/63 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1B | c.6415G>T p.G2139W | Missense Mutation (SNP) | VAF 136/312 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOT1L | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 186/200 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPEP3 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 147/157 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DRD2 | c.-29C>A | Splice Region (SNP) | VAF 81/297 reads (27%) | called by muse, mutect2, varscan2
- DROSHA | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 113/387 reads (29%) | called by muse, mutect2, varscan2
- DUSP3 | c.354C>T p.G118= | Splice Region (SNP) | VAF 174/454 reads (38%) | called by muse, mutect2, varscan2
- EBF1 | c.873A>T p.L291F | Missense Mutation (SNP) | VAF 109/116 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECEL1 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 303/485 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EGR3 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EGR3 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ELP3 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN2 | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EMX1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPG5 | c.6874A>T p.I2292F | Missense Mutation (SNP) | VAF 463/506 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EPG5 | c.3400A>T p.S1134C | Missense Mutation (SNP) | VAF 90/103 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA3 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 146/154 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EPS15 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ERBIN | c.3285G>T p.R1095S | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ERC2 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 201/209 reads (96%) | SIFT tolerated (0.51); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ERICH1 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 172/413 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESPNL | c.1882A>T p.T628S | Missense Mutation (SNP) | VAF 251/576 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ESX1 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 298/313 reads (95%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ETV1 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EXOC7 | c.1091A>T p.Y364F (on ENST00000335146 / NM_001145297.4; = p.Y282F on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/743 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EYS | c.5520G>C p.W1840C | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EYS | c.3203A>G p.D1068G | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- F2 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 217/646 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FAM114A1 | c.945+1G>T p.X315_splice | Splice Site (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- FAM135B | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 127/263 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- FAM78A | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 114/178 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASTKD3 | c.1119G>T p.R373S | Missense Mutation (SNP) | VAF 128/490 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT1 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- FAT4 | c.9285C>G p.H3095Q | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT4 | c.10204G>T p.D3402Y | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL5 | c.2317T>A p.C773S | Missense Mutation (SNP) | VAF 28/341 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2
- FCRL5 | c.2316C>A p.H772Q | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2
- FER | c.2385G>C p.K795N | Missense Mutation (SNP) | VAF 84/99 reads (85%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FFAR1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 452/469 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FFAR2 | c.256A>T p.S86C | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, varscan2
- FGD5 | c.2645G>C p.S882T | Missense Mutation (SNP) | VAF 349/530 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FGF23 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 226/775 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGNL2 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 71/100 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FLG2 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 338/776 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FLOT2 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 174/306 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FMO4 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 110/275 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FOXD1 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 374/403 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXL2 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 192/1244 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- FOXP2 | c.1352C>A p.T451K | Missense Mutation (SNP) | VAF 227/370 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FPGT | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FRMPD4 | c.3106G>T p.G1036W | Missense Mutation (SNP) | VAF 181/190 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- FRY | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 140/221 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FRYL | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSD2 | c.1708A>T p.K570* | Nonsense Mutation (SNP) | VAF 115/121 reads (95%) | called by muse, mutect2, varscan2
- FSIP2 | c.11223T>A p.N3741K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FSIP2 | c.16468C>A p.P5490T | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FSIP2 | c.17587G>C p.V5863L | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FUOM | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- GABRA6 | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 187/603 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GABRR2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 185/197 reads (94%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GEN1 | c.2144G>T p.C715F | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GJB5 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 316/669 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK2 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GLE1 | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 376/630 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GNRHR | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 224/370 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGB1 | c.7014G>T p.L2338F | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GP2 | c.971T>G p.L324R (on ENST00000381362 / NM_001007240.3; = p.L321R on NM_001502.4) | Missense Mutation (SNP) | VAF 93/101 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR15 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- GRIA4 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRID2IP | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2B | c.2219C>A p.A740E | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GRIN2C | c.3046T>A p.S1016T | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRM3 | c.1324+1G>T p.X442_splice | Splice Site (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- GRM5 | c.1885T>A p.Y629N | Missense Mutation (SNP) | VAF 134/212 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM7 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRM7 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM8 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 159/243 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GZMA | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 93/107 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- H2AC6 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 136/505 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HACE1 | c.715-1G>T p.X239_splice | Splice Site (SNP) | VAF 144/150 reads (96%) | called by muse, mutect2, varscan2
- HAVCR2 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 113/124 reads (91%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HBE1 | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 193/558 reads (35%) | called by muse, mutect2, varscan2
- HEATR9 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 232/492 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELQ | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HELZ | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 187/473 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- HERC2 | c.5578G>T p.G1860* | Nonsense Mutation (SNP) | VAF 63/70 reads (90%) | called by muse, mutect2, varscan2
- HEY1 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 120/232 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- HGFAC | c.1241C>G p.S414W | Missense Mutation (SNP) | VAF 388/802 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 196/205 reads (96%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HLA-DQA1 | c.361T>G p.S121A | Missense Mutation (SNP) | VAF 71/283 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HLA-DQA2 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 242/253 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMCN2 | c.4988G>T p.G1663V | Missense Mutation (SNP) | VAF 145/461 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA2 | c.391+7C>A | Splice Region (SNP) | VAF 51/181 reads (28%) | called by muse, mutect2, varscan2
- HSBP1 | c.182dup p.E62Gfs*6 | Frame Shift Ins (INS) | VAF 28/169 reads (17%) | called by mutect2, pindel, varscan2
- IFITM3 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, varscan2
- IGFBP2 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IGKV2D-24 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 178/430 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- IGKV3D-15 | c.23T>A p.L8H | Missense Mutation (SNP) | VAF 13/464 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- IGSF9B | c.4147G>C p.V1383L | Missense Mutation (SNP) | VAF 171/283 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IK | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 326/339 reads (96%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- INHBA | c.1144A>T p.S382C | Missense Mutation (SNP) | VAF 93/150 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INVS | c.2132G>T p.S711I | Missense Mutation (SNP) | VAF 166/183 reads (91%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IPO8 | c.1568A>G p.Q523R | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- IRS4 | c.2308T>A p.S770T | Missense Mutation (SNP) | VAF 315/325 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IRX2 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IRX4 | c.83A>C p.E28A | Missense Mutation (SNP) | VAF 161/672 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- IRX4 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 157/659 reads (24%) | called by muse, mutect2, varscan2
- ITGAD | c.1385G>C p.C462S | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ITIH5 | c.1191C>G p.S397R | Missense Mutation (SNP) | VAF 282/577 reads (49%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ITIH6 | c.505del p.Q169Nfs*3 | Frame Shift Del (DEL) | VAF 310/432 reads (72%) | called by mutect2, pindel, varscan2
- ITPRID1 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 236/409 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- JCAD | c.2327C>A p.T776K | Missense Mutation (SNP) | VAF 252/598 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 153/159 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- JSRP1 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 99/106 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- KANK1 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 206/226 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KAT6A | c.1545del p.K516Sfs*29 | Frame Shift Del (DEL) | VAF 121/278 reads (44%) | called by mutect2, pindel, varscan2
- KCNN4 | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 235/243 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- KCP | c.3018C>A p.S1006R (on ENST00000620378; = p.S1066R on NM_001366122.1) | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KDM2B | c.3547G>T p.V1183L | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KIAA1841 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- KIF13B | c.4001C>A p.A1334D | Missense Mutation (SNP) | VAF 180/400 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KIF5C | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- KLF8 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 58/62 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL31 | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 108/152 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL33 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 212/634 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL5 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KLK13 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 111/181 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP19-8 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 207/438 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KY | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 309/394 reads (78%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA1 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 242/586 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA4 | c.4900A>T p.T1634S (on ENST00000230538 / NM_001105206.3; = p.T1627S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/200 reads (89%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LAMA5 | c.7418A>C p.Q2473P | Missense Mutation (SNP) | VAF 103/162 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LBR | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 41/372 reads (11%) | called by muse, mutect2, varscan2
- LOXL3 | c.1415A>T p.Q472L | Missense Mutation (SNP) | VAF 165/349 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- LRFN5 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- LRFN5 | c.652C>G p.R218G | Missense Mutation (SNP) | VAF 158/355 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- LRGUK | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 69/98 reads (70%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRP2 | c.6682C>A p.L2228I | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC4C | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC4C | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC66 | c.1492G>C p.G498R | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- LRRC7 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRC71 | c.1012C>A p.H338N | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC74B | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 174/439 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRC8A | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 282/471 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.4993G>T p.G1665C | Missense Mutation (SNP) | VAF 206/212 reads (97%) | called by muse, mutect2, varscan2
- MAN1C1 | c.1849del p.V617* | Frame Shift Del (DEL) | VAF 174/246 reads (71%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.959dup p.P321Afs*6 | Frame Shift Ins (INS) | VAF 50/245 reads (20%) | called by mutect2, pindel, varscan2
- MBD5 | c.2845+1G>C p.X949_splice | Splice Site (SNP) | VAF 144/296 reads (49%) | called by muse, mutect2, varscan2
- MBNL1 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 102/627 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MDH1 | c.989T>C p.F330S | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- METTL17 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 210/466 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFRP | c.137G>T p.G46V (on ENST00000449574; = p.G422V on NM_031433.4) | Missense Mutation (SNP) | VAF 163/271 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MGAM2 | c.4717C>A p.L1573I | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MICAL2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 146/243 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MICU1 | c.605G>T p.G202V (on ENST00000361114 / NM_001195518.2; = p.G208V on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MMP9 | c.1881C>A p.F627L | Missense Mutation (SNP) | VAF 110/183 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- MN1 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.056); called by muse, varscan2
- MPPED2 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MRC1 | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 168/369 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MRC1 | c.2669C>A p.P890H | Missense Mutation (SNP) | VAF 240/561 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MRPL13 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 65/134 reads (49%) | called by muse, mutect2, varscan2
- MTIF2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 192/427 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTOR | c.6146A>T p.E2049V | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by mutect2, varscan2
- MTUS1 | c.1893_1895dup p.A632dup | In Frame Ins (INS) | VAF 81/542 reads (15%) | called by mutect2, pindel, varscan2
- MUC12 | c.3227A>T p.Q1076L (on ENST00000379442; = p.Q933L on NM_001164462.1) | Missense Mutation (SNP) | VAF 352/419 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MUC16 | c.22901G>T p.S7634I | Missense Mutation (SNP) | VAF 119/127 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC2 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- MUC5AC | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 188/616 reads (31%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC5B | c.11141C>G p.S3714C | Missense Mutation (SNP) | VAF 232/509 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUCL1 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 160/283 reads (57%) | called by muse, mutect2, varscan2
- MYCBPAP | c.1361A>T p.Y454F | Missense Mutation (SNP) | VAF 128/341 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MYH1 | c.3109G>T p.D1037Y | Missense Mutation (SNP) | VAF 180/197 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MYH13 | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 164/183 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 240/255 reads (94%) | called by muse, mutect2, varscan2
- MYH3 | c.3636dup p.R1213Afs*19 | Frame Shift Ins (INS) | VAF 375/551 reads (68%) | called by mutect2, pindel, varscan2
- MYH8 | c.54C>A p.Y18* | Nonsense Mutation (SNP) | VAF 14/367 reads (4%) | called by muse, mutect2
- MYLK | c.1942+4T>A | Splice Region (SNP) | VAF 490/649 reads (76%) | called by muse, mutect2, varscan2
- MYO1B | c.929G>C p.C310S | Missense Mutation (SNP) | VAF 132/259 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO1D | c.480C>G p.S160R | Missense Mutation (SNP) | VAF 78/391 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1G | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MYOF | c.874+1G>T p.X292_splice | Splice Site (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- MYOG | c.597C>A p.H199Q | Missense Mutation (SNP) | VAF 144/164 reads (88%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MYOZ1 | c.504A>G p.G168= | Splice Region (SNP) | VAF 117/263 reads (44%) | called by muse, mutect2, varscan2
- MYT1 | c.3238-1G>T p.X1080_splice | Splice Site (SNP) | VAF 57/90 reads (63%) | called by muse, mutect2, varscan2
- NALCN | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 105/169 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBEA | c.3008T>A p.I1003K | Missense Mutation (SNP) | VAF 107/156 reads (69%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBPF12 | c.2210A>C p.E737A | Missense Mutation (SNP) | VAF 183/582 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NCKAP5 | c.5047C>A p.L1683M | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NCKAP5L | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 91/143 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NDST4 | c.1499G>T p.R500I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NEB | c.7802G>A p.S2601N | Missense Mutation (SNP) | VAF 254/625 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- NEK10 | c.2552C>A p.A851D | Missense Mutation (SNP) | VAF 100/108 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NELL1 | c.1838G>T p.C613F | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEUROD1 | c.752del p.A251Efs*11 | Frame Shift Del (DEL) | VAF 278/727 reads (38%) | called by mutect2, pindel, varscan2
- NFASC | c.904C>G p.R302G (on ENST00000339876 / NM_001378329.1; = p.R313G on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/77 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- NFIC | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 188/211 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFIC | c.457A>C p.K153Q | Missense Mutation (SNP) | VAF 359/379 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NGF | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 79/121 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NKX2-5 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 239/248 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NLGN1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 104/496 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NME8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 158/271 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NOG | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.575A>T p.Q192L | Missense Mutation (SNP) | VAF 106/346 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NPTX1 | c.686A>C p.Q229P | Missense Mutation (SNP) | VAF 171/500 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- NPY5R | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NRROS | c.1642T>A p.L548M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- NRXN3 | c.1791G>T p.E597D (on ENST00000335750 / NM_001330195.2; = p.E224D on NM_004796.6) | Missense Mutation (SNP) | VAF 285/306 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NSMF | c.620_626del p.R207Lfs*49 (on ENST00000371475 / NM_001130969.3; = p.R207Lfs*47 on NM_015537.4) | Frame Shift Del (DEL) | VAF 254/522 reads (49%) | called by mutect2, pindel, varscan2
- NTSR1 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- OR10AG1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 100/153 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR10AG1 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR10D3 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- OR10J1 | c.570C>A p.D190E | Missense Mutation (SNP) | VAF 180/366 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- OR10V1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 88/127 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13C3 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR13D1 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- OR1N2 | c.68G>C p.W23S | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- OR2D2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2T6 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 114/119 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4C11 | c.501T>A p.C167* | Nonsense Mutation (SNP) | VAF 80/252 reads (32%) | called by muse, mutect2, varscan2
- OR4K17 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 121/409 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- OR4S2 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 95/179 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51G2 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- OR51Q1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 163/257 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR6C1 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 165/290 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N1 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6P1 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR8S1 | c.59A>C p.D20A | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR9I1 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 109/163 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- OR9K2 | c.364dup p.C122Lfs*15 (on ENST00000305377; = p.C100Lfs*15 on NM_001005243.1) | Frame Shift Ins (INS) | VAF 128/275 reads (47%) | called by mutect2, pindel, varscan2
- P2RY14 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 401/529 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAQR5 | c.446A>T p.H149L | Missense Mutation (SNP) | VAF 235/252 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PATL2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PAWR | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 86/134 reads (64%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PCARE | c.2645T>A p.L882Q | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDHB10 | c.2347A>T p.R783W | Missense Mutation (SNP) | VAF 144/150 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PCDHB15 | c.1555C>A p.L519M | Missense Mutation (SNP) | VAF 917/971 reads (94%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PCDHB3 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 220/235 reads (94%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PCLO | c.5686A>G p.T1896A | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PDCD11 | c.3369-1G>T p.X1123_splice | Splice Site (SNP) | VAF 101/246 reads (41%) | called by muse, mutect2, varscan2
- PDE1C | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PDE5A | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PDZRN4 | c.571del p.R191Gfs*37 | Frame Shift Del (DEL) | VAF 95/394 reads (24%) | called by mutect2, pindel, varscan2
- PEAR1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PEG3 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 126/131 reads (96%) | called by muse, mutect2, varscan2
- PEX16 | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 147/235 reads (63%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PFAS | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 145/149 reads (97%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGK2 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 73/313 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PIK3R2 | c.1956_1957insT p.G653Wfs*158 | Frame Shift Ins (INS) | VAF 123/173 reads (71%) | called by mutect2, pindel, varscan2
- PITRM1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 145/366 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKD2 | c.2136G>T p.L712F | Missense Mutation (SNP) | VAF 80/307 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PKHD1 | c.7128C>A p.Y2376* | Nonsense Mutation (SNP) | VAF 100/363 reads (28%) | called by muse, mutect2, varscan2
- PLA2G1B | c.215A>C p.N72T | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PLB1 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 95/332 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB1 | c.2473A>T p.K825* | Nonsense Mutation (SNP) | VAF 100/257 reads (39%) | called by muse, mutect2, varscan2
- PLCE1 | c.1809+1G>T p.X603_splice | Splice Site (SNP) | VAF 149/312 reads (48%) | called by muse, mutect2, varscan2
- PLCL1 | c.470del p.K157Sfs*7 | Frame Shift Del (DEL) | VAF 81/231 reads (35%) | called by mutect2, pindel, varscan2
- PLCL1 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PLEKHA5 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 111/175 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PLEKHH2 | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PLEKHS1 | c.1349T>A p.F450Y | Missense Mutation (SNP) | VAF 68/349 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PLEKHS1 | c.1350C>G p.F450L | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLOD1 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 342/354 reads (97%) | called by muse, mutect2, varscan2
- PLOD3 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLSCR2 | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 122/601 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- POLQ | c.6227dup p.E2077Gfs*19 | Frame Shift Ins (INS) | VAF 24/182 reads (13%) | called by pindel, varscan2
- POP1 | c.2945dup p.F984Vfs*3 | Frame Shift Ins (INS) | VAF 23/122 reads (19%) | called by pindel, varscan2
- POTEE | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 156/810 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- POU4F2 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, varscan2
- PPCS | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PPP1R9A | c.2833A>T p.K945* | Nonsense Mutation (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- PPRC1 | c.4756G>T p.V1586F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF15 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 128/789 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PRF1 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 235/504 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRG4 | c.3677_3703del p.A1226_K1234del | In Frame Del (DEL) | VAF 90/432 reads (21%) | called by mutect2, pindel
- PRKCSH | c.1249_1258dup p.T420Rfs*50 | Frame Shift Ins (INS) | VAF 124/199 reads (62%) | called by mutect2, varscan2
- PRKN | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 212/230 reads (92%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PRLR | c.1461C>A p.D487E | Missense Mutation (SNP) | VAF 408/598 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROM2 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRSS1 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 111/637 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PRSS21 | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 92/99 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- PSMD8 | c.802A>G p.R268G | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTBP2 | c.1390A>C p.T464P (on ENST00000426398 / NM_001300986.2; = p.T456P on NM_021190.4) | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTCD1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTCHD3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- PTCHD4 | c.2236C>G p.Q746E | Missense Mutation (SNP) | VAF 209/340 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTGIS | c.446T>A p.L149* | Nonsense Mutation (SNP) | VAF 93/354 reads (26%) | called by muse, mutect2, varscan2
- PTPN12 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PTPRA | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 159/316 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRB | c.3832G>C p.A1278P | Missense Mutation (SNP) | VAF 182/273 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PTPRB | c.2612C>A p.T871N | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PTPRH | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 267/280 reads (95%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PTPRM | c.4094T>C p.L1365S | Missense Mutation (SNP) | VAF 152/355 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRZ1 | c.3377A>T p.Q1126L | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PURG | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 161/352 reads (46%) | called by muse, mutect2, varscan2
- PXDN | c.2273C>A p.A758D | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PXYLP1 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 68/321 reads (21%) | called by muse, mutect2, varscan2
- R3HDM1 | c.1623G>T p.Q541H | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- RAB3IP | c.622G>T p.E208* (on ENST00000550536 / NM_175623.4; = p.E192* on NM_022456.5) | Nonsense Mutation (SNP) | VAF 24/185 reads (13%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 167/363 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RADIL | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RAP1GAP2 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RASSF4 | c.760A>T p.R254W | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RASSF9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 98/134 reads (73%) | called by muse, mutect2, varscan2
- RB1 | c.2520+2dup p.X840_splice | Splice Site (INS) | VAF 30/180 reads (17%) | called by mutect2, pindel, varscan2
- RECQL4 | c.2980G>C p.D994H | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RERE | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 95/459 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RESP18 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RGS21 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RICTOR | c.2114T>C p.L705S | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.776A>T p.Y259F (on ENST00000666250 / NM_001348490.2; = p.Y67F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RNF207 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 101/536 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RNPC3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RREB1 | c.3038A>T p.Q1013L | Missense Mutation (SNP) | VAF 111/179 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- RSPH14 | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 113/216 reads (52%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTN4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR2 | c.12832G>T p.D4278Y | Missense Mutation (SNP) | VAF 136/356 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SAMHD1 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 182/352 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SAP18 | c.115C>A p.R39S (on ENST00000607003; = p.R58S on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 217/237 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SCFD1 | c.412A>T p.S138C | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SCFD2 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- SCN9A | c.4762A>T p.I1588F (on ENST00000303354; = p.I1577F on NM_002977.3) | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SCNN1A | c.1403A>C p.H468P | Missense Mutation (SNP) | VAF 419/651 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SEC24C | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SELENOW | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 298/315 reads (95%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB11 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 94/107 reads (88%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SERPINC1 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 186/424 reads (44%) | called by muse, mutect2, varscan2
- SF3A1 | c.2237A>T p.E746V | Missense Mutation (SNP) | VAF 166/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SH2D4B | c.528A>T p.E176D | Missense Mutation (SNP) | VAF 136/271 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SH3BP5L | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 115/131 reads (88%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC1 | c.4061del p.F1354Sfs*11 | Frame Shift Del (DEL) | VAF 72/201 reads (36%) | called by mutect2, pindel
- SIGLECL1 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 216/225 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIX5 | c.1997C>G p.S666* | Nonsense Mutation (SNP) | VAF 353/602 reads (59%) | called by muse, mutect2, varscan2
- SLC16A7 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A16 | c.61_69del p.Q21_A23del | In Frame Del (DEL) | VAF 111/254 reads (44%) | called by mutect2, pindel, varscan2
502 further variants in this file (129 protein-altering or splice-affecting, 247 silent, 126 other) are not listed here.
